Somatic mutation profile of cancer-model specimen HCM-WCMC-0951-C67-85A (3D Organoid; aliquot HCM-WCMC-0951-C67-85A-01D-A88H-36), derived from the primary tumor of HCMI case HCM-WCMC-0951-C67, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; Age at diagnosis: 90 years or older (exact value withheld by GDC).
Specimen HCM-WCMC-0951-C67-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 941f48ea-6826-41c6-b91c-c42e67ff83c2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-WCMC-0951-C67-10A (Blood Derived Normal), aliquot HCM-WCMC-0951-C67-10A-01D-A88H-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d43a4bce-9ca0-4243-928d-1399006820be

The open-access MAF lists 210 somatic variants for this specimen: 142 protein-altering or splice-affecting, 60 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 131, Silent 60, Nonsense Mutation 5, Intron 4, Splice Site 3, 5'Flank 2, 3'UTR 2, Frame Shift Ins 1, Splice Region 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NF1 | c.1721+1G>A p.X574_splice | Splice Site (SNP) | VAF 83/211 reads (39%) | catalogued as rs1131691096, CS086408, CS1311510, CS1311511, COSV100645920; ClinVar: pathogenic; called by muse, mutect2, varscan2
- NF1 | c.6705-1G>C p.X2235_splice (on ENST00000358273 / NM_001042492.3; = p.X2214_splice on NM_000267.3) | Splice Site (SNP) | VAF 82/172 reads (48%) | catalogued as rs1060500356, CS000886, COSV62198415; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.587G>A p.R196Q | Missense Mutation (SNP) | VAF 162/169 reads (96%) | hotspot (GDC flag); SIFT tolerated (0.07); PolyPhen possibly damaging (0.86); catalogued as rs483352697, CM984587, COSV52667931, COSV52674826, COSV52678297; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ADGRL3 | c.3215G>A p.R1072K (on ENST00000506720 / NM_001322402.2; = p.R1004K on NM_015236.6) | Missense Mutation (SNP) | VAF 107/112 reads (96%) | SIFT tolerated (0.27); PolyPhen benign (0.163); catalogued as COSV72230729; called by muse, mutect2, varscan2
- ANK3 | c.12703G>C p.D4235H (on ENST00000280772 / NM_001320874.2; = p.D859H on NM_001149.3) | Missense Mutation (SNP) | VAF 99/226 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.974); catalogued as COSV55047527; called by muse, mutect2, varscan2
- APOB | c.13395G>C p.K4465N | Missense Mutation (SNP) | VAF 203/424 reads (48%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.946); catalogued as rs1287901082; called by muse, mutect2, varscan2
- ASNS | c.1220G>T p.R407L | Missense Mutation (SNP) | VAF 141/306 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs748291290, COSV51554301; called by muse, mutect2, varscan2
- BIRC6 | c.10280C>A p.S3427Y | Missense Mutation (SNP) | VAF 119/281 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV101429129; called by muse, mutect2, varscan2
- CA14 | c.938G>C p.R313T | Missense Mutation (SNP) | VAF 66/176 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.051); catalogued as rs1553848697; called by mutect2, varscan2
- CASR | c.937G>A p.V313M | Missense Mutation (SNP) | VAF 208/426 reads (49%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.885); catalogued as rs200838528; called by muse, mutect2, varscan2
- CD5L | c.94C>T p.R32C | Missense Mutation (SNP) | VAF 193/350 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs1307024327, COSV100941106; called by muse, mutect2, varscan2
- CGNL1 | c.946G>A p.D316N | Missense Mutation (SNP) | VAF 195/444 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.024); catalogued as COSV55570830; called by muse, mutect2, varscan2
- CTNNA2 | c.1012G>A p.V338M | Missense Mutation (SNP) | VAF 204/432 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs768529296, COSV63553496, COSV63606300; called by muse, varscan2
- DCAF12L2 | c.1283C>T p.P428L | Missense Mutation (SNP) | VAF 378/791 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.454); catalogued as COSV100758954; called by muse, mutect2
- DCAF5 | c.2659G>C p.E887Q | Missense Mutation (SNP) | VAF 186/391 reads (48%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.102); catalogued as COSV100432305; called by muse, mutect2, varscan2
- DIDO1 | c.6200C>T p.S2067L | Missense Mutation (SNP) | VAF 256/560 reads (46%) | SIFT tolerated (0.26); PolyPhen benign (0.012); catalogued as COSV99825685; called by muse, mutect2, varscan2
- DNAH14 | c.6735G>C p.L2245F (on ENST00000445597; = p.L2898F on NM_001367479.1) | Missense Mutation (SNP) | VAF 109/265 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.401); catalogued as COSV59903516; called by muse, mutect2, varscan2
- DNAH8 | c.11483C>G p.S3828C | Missense Mutation (SNP) | VAF 63/175 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.141); catalogued as COSV100544413; called by muse, mutect2, varscan2
- EDRF1 | c.3634C>G p.L1212V (on ENST00000356792 / NM_001202438.2; = p.L1178V on NM_015608.2) | Missense Mutation (SNP) | VAF 198/408 reads (49%) | SIFT deleterious (0.04); PolyPhen benign (0.01); catalogued as COSV61764122; called by muse, mutect2, varscan2
- FAM124A | c.800C>T p.T267M (on ENST00000322475 / NM_001242312.2; = p.T303M on NM_145019.4) | Missense Mutation (SNP) | VAF 406/416 reads (98%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs775058541, COSV54475891; called by muse, mutect2, varscan2
- FAM171A1 | c.76G>A p.E26K | Missense Mutation (SNP) | VAF 160/347 reads (46%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs1264049602, COSV100968217; called by muse, mutect2, varscan2
- GPR158 | c.2332G>A p.D778N | Missense Mutation (SNP) | VAF 194/435 reads (45%) | SIFT tolerated (0.15); PolyPhen benign (0.098); catalogued as rs747693904, COSV66266831; called by muse, mutect2, varscan2
- IGLV1-40 | c.168G>A p.W56* | Nonsense Mutation (SNP) | VAF 240/482 reads (50%) | catalogued as rs752483277; called by muse, mutect2, varscan2
- KDM5A | c.3747G>C p.L1249F | Missense Mutation (SNP) | VAF 228/522 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV66991129; called by muse, mutect2, varscan2
- LRP2 | c.10630G>T p.E3544* | Nonsense Mutation (SNP) | VAF 94/289 reads (33%) | catalogued as COSV55549152, COSV55570262; called by muse, mutect2, varscan2
- MKNK2 | c.682G>C p.D228H | Missense Mutation (SNP) | VAF 256/541 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51731925; called by muse, mutect2, varscan2
- MUC16 | c.6296C>T p.S2099F | Missense Mutation (SNP) | VAF 191/446 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.919); catalogued as COSV101198404; called by muse, mutect2, varscan2
- MYH15 | c.1274G>C p.R425T | Missense Mutation (SNP) | VAF 137/322 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.793); catalogued as COSV99843478; called by muse, mutect2, varscan2
- NF1 | c.2498C>G p.S833C | Missense Mutation (SNP) | VAF 140/325 reads (43%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as COSV62191525; called by muse, mutect2, varscan2
- NPHS1 | c.2509G>T p.A837S | Missense Mutation (SNP) | VAF 24/420 reads (6%) | SIFT tolerated (0.27); PolyPhen benign (0.058); catalogued as rs150623032; called by muse, mutect2
- NTRK3 | c.1523T>A p.I508N | Missense Mutation (SNP) | VAF 219/490 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.969); catalogued as COSV58119961; called by muse, mutect2, varscan2
- OR2L13 | c.229G>A p.V77I | Missense Mutation (SNP) | VAF 153/449 reads (34%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.985); catalogued as COSV63547540, COSV63561899; called by muse, mutect2, varscan2
- PCDH17 | c.2512G>A p.G838R | Missense Mutation (SNP) | VAF 378/390 reads (97%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.493); catalogued as rs1485429803; called by muse, mutect2, varscan2
- PCDHA5 | c.1519G>A p.V507I | Missense Mutation (SNP) | VAF 47/370 reads (13%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.08); catalogued as rs782079862; called by muse, mutect2, varscan2
- PCDHAC1 | c.2269C>G p.R757G | Missense Mutation (SNP) | VAF 189/193 reads (98%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV99037744; called by muse, mutect2, varscan2
- PCDHB12 | c.1523C>T p.A508V | Missense Mutation (SNP) | VAF 378/386 reads (98%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.062); catalogued as COSV53397189, COSV53401737; called by muse, mutect2, varscan2
- PCDHB4 | c.305T>C p.V102A | Missense Mutation (SNP) | VAF 177/178 reads (99%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.852); catalogued as rs1554274320, COSV52020114; called by muse, mutect2, varscan2
- PEG3 | c.2936C>A p.A979D | Missense Mutation (SNP) | VAF 205/422 reads (49%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.825); catalogued as COSV99687820; called by muse, mutect2, varscan2
- PLEKHH3 | c.1417G>C p.E473Q | Missense Mutation (SNP) | VAF 178/354 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV52217386; called by muse, varscan2
- POLRMT | c.1799C>T p.S600F | Missense Mutation (SNP) | VAF 178/422 reads (42%) | SIFT deleterious (0.05); PolyPhen benign (0.396); catalogued as rs749713903; called by muse, mutect2, varscan2
- POTEI | c.2860T>C p.W954R | Missense Mutation (SNP) | VAF 32/270 reads (12%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs1180587103; called by mutect2, varscan2
- PTEN | c.29G>A p.S10N | Missense Mutation (SNP) | VAF 35/127 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.123); catalogued as COSV64289204, COSV64299108; called by muse, mutect2, varscan2
- RAB24 | c.112C>T p.Q38* | Nonsense Mutation (SNP) | VAF 196/200 reads (98%) | catalogued as COSV57463097; called by muse, mutect2, varscan2
- REM1 | c.608G>C p.R203P | Missense Mutation (SNP) | VAF 140/332 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52427833; called by muse, mutect2
- RHOB | c.223C>A p.P75T | Missense Mutation (SNP) | VAF 333/642 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.61); catalogued as COSV55355269, COSV55355916; called by muse, mutect2, varscan2
- RPL35 | c.40A>G p.K14E | Missense Mutation (SNP) | VAF 30/296 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.046); catalogued as rs750326021; called by muse, mutect2
- RPL4 | c.392C>T p.S131L | Missense Mutation (SNP) | VAF 157/321 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.33); catalogued as rs374208882; called by muse, mutect2, varscan2
- SALL3 | c.917C>T p.A306V | Missense Mutation (SNP) | VAF 57/125 reads (46%) | SIFT tolerated (0.14); PolyPhen benign (0.011); catalogued as rs1393573993; called by muse, mutect2, varscan2
- SERPINA12 | c.375G>C p.Q125H | Missense Mutation (SNP) | VAF 170/379 reads (45%) | SIFT tolerated (0.14); PolyPhen benign (0.065); catalogued as COSV57943677, COSV57943932; called by muse, mutect2, varscan2
- SLC22A12 | c.1460G>A p.R487Q | Missense Mutation (SNP) | VAF 286/652 reads (44%) | SIFT tolerated (0.12); PolyPhen benign (0.027); catalogued as rs151308640, COSV100327850; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SLC24A2 | c.1562C>T p.A521V | Missense Mutation (SNP) | VAF 122/122 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1275622190, COSV53864937; called by muse, mutect2, varscan2
- SLC4A2 | c.737G>T p.G246V | Missense Mutation (SNP) | VAF 330/654 reads (50%) | SIFT deleterious (0.03); PolyPhen benign (0.396); catalogued as COSV59658815; called by muse, mutect2, varscan2
- SLC9A8 | c.46C>T p.H16Y | Missense Mutation (SNP) | VAF 180/359 reads (50%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.069); catalogued as rs776384524; called by muse, mutect2, varscan2
- SMU1 | c.947C>T p.S316F | Missense Mutation (SNP) | VAF 149/151 reads (99%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.938); catalogued as COSV68140157; called by muse, mutect2, varscan2
- TLN2 | c.1971G>C p.Q657H | Missense Mutation (SNP) | VAF 129/299 reads (43%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as rs1326999599, COSV60890138, COSV60890787; called by muse, mutect2, varscan2
- TMEM179B | c.80C>G p.A27G | Missense Mutation (SNP) | VAF 252/556 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0.186); catalogued as rs1248126688; called by muse, mutect2, varscan2
- TMEM259 | c.1014G>C p.Q338H | Missense Mutation (SNP) | VAF 214/467 reads (46%) | SIFT tolerated (0.1); PolyPhen benign (0.378); catalogued as rs927159027; called by muse, mutect2, varscan2
- TMEM74B | c.616C>T p.R206C | Missense Mutation (SNP) | VAF 296/626 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); catalogued as rs775554427, COSV67891814; called by muse, mutect2, varscan2
- TNIP3 | c.571G>A p.E191K | Missense Mutation (SNP) | VAF 23/363 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.786); catalogued as COSV50247577; called by muse, mutect2
- TNRC18 | c.8047G>A p.D2683N | Missense Mutation (SNP) | VAF 326/650 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.894); catalogued as rs1306379608; called by muse, varscan2
- TRPM1 | c.2300G>A p.R767H | Missense Mutation (SNP) | VAF 14/340 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as rs372228723; called by muse, mutect2
- UTP20 | c.2938G>C p.E980Q | Missense Mutation (SNP) | VAF 74/184 reads (40%) | SIFT tolerated (0.1); PolyPhen benign (0.231); catalogued as COSV55384197; called by muse, mutect2, varscan2
- UTRN | c.1868C>A p.S623Y | Missense Mutation (SNP) | VAF 124/312 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.398); catalogued as rs1023345664; called by muse, mutect2, varscan2
- VWA8 | c.2002C>T p.R668W | Missense Mutation (SNP) | VAF 143/307 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs765958170, COSV55697618; called by muse, mutect2, varscan2
- XKR4 | c.1939G>A p.E647K | Missense Mutation (SNP) | VAF 85/431 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV59312916; called by muse, mutect2, varscan2
- ZFP36L2 | c.632G>A p.R211H | Missense Mutation (SNP) | VAF 357/686 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV56697653; called by muse, mutect2, varscan2
- ZNF180 | c.148C>G p.Q50E | Missense Mutation (SNP) | VAF 153/317 reads (48%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.45); catalogued as COSV55419638, COSV55421868; called by muse, mutect2, varscan2
- ZNF34 | c.900G>A p.M300I | Missense Mutation (SNP) | VAF 569/577 reads (99%) | SIFT tolerated (1); PolyPhen benign (0.022); catalogued as rs369409033; called by muse, mutect2, varscan2
- ZUP1 | c.1383G>C p.W461C | Missense Mutation (SNP) | VAF 120/287 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100884949; called by muse, mutect2, varscan2
- ADCY8 | c.2059C>T p.H687Y | Missense Mutation (SNP) | VAF 733/738 reads (99%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.623); called by muse, mutect2, varscan2
- ADH1C | c.1003G>A p.D335N | Missense Mutation (SNP) | VAF 99/216 reads (46%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.896); called by muse, mutect2, varscan2
- ADRB1 | c.977T>A p.L326Q | Missense Mutation (SNP) | VAF 199/416 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- AMBN | c.811G>A p.D271N | Missense Mutation (SNP) | VAF 138/301 reads (46%) | SIFT deleterious (0.04); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ASB12 | c.556T>A p.Y186N | Missense Mutation (SNP) | VAF 316/632 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- ASTN2 | c.2003G>A p.C668Y (on ENST00000313400 / NM_001365069.1; = p.C617Y on NM_014010.5) | Missense Mutation (SNP) | VAF 200/202 reads (99%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, varscan2
- BRI3BP | c.17C>T p.S6L | Missense Mutation (SNP) | VAF 176/382 reads (46%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.012); called by muse, varscan2
- C2CD3 | c.6705G>C p.Q2235H | Missense Mutation (SNP) | VAF 199/603 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.815); called by muse, mutect2, varscan2
- CACNA2D3 | c.1927G>C p.E643Q | Missense Mutation (SNP) | VAF 126/309 reads (41%) | SIFT tolerated (0.57); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- CADM4 | c.442C>T p.P148S | Missense Mutation (SNP) | VAF 265/616 reads (43%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.903); called by muse, mutect2, varscan2
- CDH6 | c.850G>T p.G284W | Missense Mutation (SNP) | VAF 160/447 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- COL6A5 | c.959A>G p.Q320R | Missense Mutation (SNP) | VAF 174/353 reads (49%) | SIFT tolerated (0.4); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- DARS2 | c.266T>G p.L89R | Missense Mutation (SNP) | VAF 79/193 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.94); called by mutect2, varscan2
- DCAF5 | c.2794G>C p.E932Q | Missense Mutation (SNP) | VAF 137/291 reads (47%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.558); called by muse, mutect2, varscan2
- DCC | c.3043G>C p.D1015H | Missense Mutation (SNP) | VAF 211/212 reads (100%) | SIFT deleterious (0); PolyPhen possibly damaging (0.89); called by muse, mutect2, varscan2
- DCHS1 | c.4865C>T p.S1622L | Missense Mutation (SNP) | VAF 247/842 reads (29%) | SIFT tolerated (0.3); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- DDX55 | c.1511G>C p.R504T | Missense Mutation (SNP) | VAF 138/315 reads (44%) | SIFT tolerated (0.26); PolyPhen benign (0); called by muse, mutect2, varscan2
- DENND4A | c.2107C>G p.L703V | Missense Mutation (SNP) | VAF 104/245 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- DOCK7 | c.4021G>A p.E1341K (on ENST00000635253 / NM_001367561.1; = p.E1310K on NM_033407.3) | Missense Mutation (SNP) | VAF 128/345 reads (37%) | SIFT tolerated (0.64); PolyPhen benign (0.146); called by muse, mutect2, varscan2
- ELF3 | c.1005dup p.Y336Lfs*135 | Frame Shift Ins (INS) | VAF 101/228 reads (44%) | called by mutect2, pindel, varscan2
- EML3 | c.2040T>A p.N680K | Missense Mutation (SNP) | VAF 194/356 reads (54%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ESR1 | c.578C>T p.S193L | Missense Mutation (SNP) | VAF 203/410 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FBXO15 | c.704G>C p.C235S | Missense Mutation (SNP) | VAF 217/497 reads (44%) | SIFT tolerated (0.45); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- FBXW9 | c.169_170del p.A57Rfs*19 | Frame Shift Del (DEL) | VAF 259/689 reads (38%) | called by mutect2, pindel, varscan2
- FGL2 | c.1218C>G p.F406L | Missense Mutation (SNP) | VAF 212/420 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.673); called by muse, mutect2, varscan2
- FLII | c.1217C>A p.S406Y | Missense Mutation (SNP) | VAF 176/181 reads (97%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.733); called by muse, mutect2, varscan2
- GBA3 | c.68A>G p.D23G | Missense Mutation (SNP) | VAF 90/196 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.668); called by muse, mutect2, varscan2
- GSR | c.310A>C p.N104H | Missense Mutation (SNP) | VAF 64/64 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HEATR5A | c.5228G>A p.C1743Y | Missense Mutation (SNP) | VAF 135/264 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- IGSF21 | c.619C>G p.Q207E | Missense Mutation (SNP) | VAF 210/373 reads (56%) | SIFT tolerated (0.82); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- KIF3A | c.2051+1G>C p.X684_splice | Splice Site (SNP) | VAF 93/97 reads (96%) | called by muse, mutect2, varscan2
- KLHL24 | c.137C>T p.S46L | Missense Mutation (SNP) | VAF 134/298 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- KLHL34 | c.65T>A p.L22Q | Missense Mutation (SNP) | VAF 199/442 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KRT23 | c.566C>T p.T189I | Missense Mutation (SNP) | VAF 225/514 reads (44%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- LCT | c.4195G>A p.D1399N | Missense Mutation (SNP) | VAF 110/291 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.716); called by muse, mutect2, varscan2
- MED13L | c.4969G>A p.E1657K | Missense Mutation (SNP) | VAF 109/246 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.3); called by muse, mutect2, varscan2
- MIB2 | c.630G>T p.K210N | Missense Mutation (SNP) | VAF 150/338 reads (44%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.864); called by mutect2, varscan2
- MIP | c.146G>A p.G49D | Missense Mutation (SNP) | VAF 27/575 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2
- MLIP | c.375C>G p.F125L | Missense Mutation (SNP) | VAF 208/469 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- MYH10 | c.2572G>C p.D858H | Missense Mutation (SNP) | VAF 167/172 reads (97%) | SIFT deleterious (0); PolyPhen possibly damaging (0.669); called by muse, mutect2, varscan2
- NEU3 | c.76G>A p.E26K | Missense Mutation (SNP) | VAF 220/713 reads (31%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NR2C2AP | c.250C>A p.Q84K | Missense Mutation (SNP) | VAF 211/457 reads (46%) | SIFT tolerated (0.51); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- NSFL1C | c.617A>T p.N206I | Missense Mutation (SNP) | VAF 99/269 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OSBPL10 | c.1239G>C p.L413F | Missense Mutation (SNP) | VAF 96/223 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PADI3 | c.1856C>T p.S619F | Missense Mutation (SNP) | VAF 131/324 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- PHIP | c.4610C>G p.S1537C | Missense Mutation (SNP) | VAF 111/224 reads (50%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.241); called by muse, mutect2, varscan2
- PLA2G3 | c.916C>T p.Q306* | Nonsense Mutation (SNP) | VAF 291/616 reads (47%) | called by muse, mutect2, varscan2
- RAB24 | c.607C>T p.H203Y | Missense Mutation (SNP) | VAF 138/140 reads (99%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.097); called by muse, mutect2, varscan2
- RAD54L2 | c.2665G>A p.V889M | Missense Mutation (SNP) | VAF 123/248 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- RAG2 | c.500G>A p.R167K | Missense Mutation (SNP) | VAF 176/391 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- RECQL5 | c.984C>T p.V328= | Splice Region (SNP) | VAF 105/250 reads (42%) | called by muse, mutect2, varscan2
- REV1 | c.2102G>C p.R701T | Missense Mutation (SNP) | VAF 115/307 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.673); called by muse, mutect2, varscan2
- RIMKLB | c.1054G>T p.D352Y | Missense Mutation (SNP) | VAF 264/515 reads (51%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.543); called by muse, mutect2, varscan2
- RYR3 | c.11449G>T p.E3817* (on ENST00000389232; = p.E3818* on NM_001036.6) | Nonsense Mutation (SNP) | VAF 93/237 reads (39%) | called by mutect2, varscan2
- SHROOM3 | c.2506G>C p.E836Q | Missense Mutation (SNP) | VAF 204/438 reads (47%) | SIFT tolerated (0.08); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- SKIDA1 | c.1960G>A p.D654N | Missense Mutation (SNP) | VAF 192/420 reads (46%) | SIFT tolerated (0.11); PolyPhen benign (0.185); called by muse, mutect2, varscan2
- SPATA7 | c.1447G>C p.E483Q | Missense Mutation (SNP) | VAF 153/297 reads (52%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.54); called by muse, mutect2, varscan2
- SUCO | c.3176G>A p.C1059Y | Missense Mutation (SNP) | VAF 88/192 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- TEX11 | c.911T>C p.L304P (on ENST00000344304; = p.L289P on NM_031276.3) | Missense Mutation (SNP) | VAF 14/316 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- TGFB2 | c.1117G>A p.E373K | Missense Mutation (SNP) | VAF 112/290 reads (39%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.899); called by muse, mutect2, varscan2
- TNRC18 | c.172C>T p.L58F | Missense Mutation (SNP) | VAF 198/453 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- TPTE | c.767G>A p.R256K (on ENST00000618007 / NM_199261.4; = p.R238K on NM_199259.4) | Missense Mutation (SNP) | VAF 48/616 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2
- TRPC7 | c.269A>G p.H90R | Missense Mutation (SNP) | VAF 281/288 reads (98%) | SIFT tolerated (0.05); PolyPhen benign (0.366); called by muse, mutect2, varscan2
- UGT2B28 | c.615G>C p.M205I | Missense Mutation (SNP) | VAF 86/214 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, varscan2
- UNC45A | c.2047A>T p.T683S | Missense Mutation (SNP) | VAF 168/332 reads (51%) | SIFT tolerated (0.51); PolyPhen benign (0); called by muse, mutect2, varscan2
- WDR72 | c.442C>T p.H148Y | Missense Mutation (SNP) | VAF 202/430 reads (47%) | SIFT tolerated (0.47); PolyPhen probably damaging (0.915); called by muse, mutect2, varscan2
- XIRP1 | c.418G>C p.D140H | Missense Mutation (SNP) | VAF 258/525 reads (49%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.452); called by muse, mutect2, varscan2
- YAF2 | c.103G>A p.E35K | Missense Mutation (SNP) | VAF 172/384 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- ZFHX4 | c.4165G>A p.V1389I | Missense Mutation (SNP) | VAF 38/882 reads (4%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.986); called by muse, mutect2
- ZMAT4 | c.422G>C p.R141T | Missense Mutation (SNP) | VAF 243/253 reads (96%) | SIFT tolerated (0.17); PolyPhen benign (0.165); called by muse, mutect2, varscan2
- ZSCAN20 | c.1776G>C p.Q592H | Missense Mutation (SNP) | VAF 149/381 reads (39%) | SIFT tolerated (0.13); PolyPhen benign (0.436); called by muse, mutect2, varscan2
- ZSWIM4 | c.23G>A p.R8Q | Missense Mutation (SNP) | VAF 241/510 reads (47%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- ZXDC | c.443C>T p.S148F | Missense Mutation (SNP) | VAF 346/700 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- ABCB5 | c.2319C>T p.F773= (on ENST00000404938 / NM_001163941.2; = p.F328= on NM_178559.6) | Silent (SNP) | VAF 119/265 reads (45%) | called by muse, mutect2, varscan2
- ABCG1 | c.96G>A p.S32= | Silent (SNP) | VAF 116/270 reads (43%) | catalogued as rs554693689; called by muse, mutect2, varscan2
- ACADVL | c.1377G>C p.R459= | Silent (SNP) | VAF 162/173 reads (94%) | called by muse, mutect2, varscan2
- ACOT12 | c.84G>C p.A28= | Silent (SNP) | VAF 233/236 reads (99%) | catalogued as rs1411965319; called by muse, mutect2, varscan2
- ACOX1 | c.237C>T p.I79= | Silent (SNP) | VAF 164/316 reads (52%) | catalogued as rs201703373, COSV53132518, COSV53135362; called by muse, mutect2, varscan2
- ACTR3 | c.90C>T p.I30= | Silent (SNP) | VAF 70/231 reads (30%) | called by muse, mutect2, varscan2
- ARHGAP22 | c.1893G>C p.L631= | Silent (SNP) | VAF 144/302 reads (48%) | catalogued as COSV50940192; called by muse, mutect2, varscan2
- ARHGAP23 | c.2574C>T p.L858= | Silent (SNP) | VAF 121/285 reads (42%) | called by muse, mutect2, varscan2
- CAMSAP2 | c.4470G>A p.*1490= (on ENST00000236925 / NM_001297707.2; = p.*1479= on NM_203459.3) | Silent (SNP) | VAF 75/182 reads (41%) | catalogued as rs747361122; called by muse, mutect2, varscan2
- CD8A | c.141G>A p.L47= | Silent (SNP) | VAF 337/652 reads (52%) | catalogued as rs1378213693; called by muse, mutect2, varscan2
- CDYL | c.1749G>A p.G583= (on ENST00000328908 / NM_001368125.1; = p.G529= on NM_004824.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 136/291 reads (47%) | called by muse, mutect2, varscan2
- CFAP91 | c.378G>A p.Q126= | Silent (SNP) | VAF 81/192 reads (42%) | called by muse, mutect2, varscan2
- CREBBP | c.6105G>A p.L2035= | Silent (SNP) | VAF 274/519 reads (53%) | called by muse, mutect2, varscan2
- ELMOD3 | c.387G>A p.R129= | Silent (SNP) | VAF 159/346 reads (46%) | called by muse, mutect2, varscan2
- EMX1 | c.807C>T p.I269= | Silent (SNP) | VAF 291/567 reads (51%) | catalogued as COSV50689322; called by muse, mutect2, varscan2
- FAM220A | c.477A>G p.Q159= | Silent (SNP) | VAF 223/423 reads (53%) | catalogued as rs142051673; called by muse, mutect2, varscan2
- FLVCR2 | c.336C>T p.F112= | Silent (SNP) | VAF 268/534 reads (50%) | catalogued as COSV53162333, COSV99471323; called by muse, mutect2, varscan2
- FLVCR2 | c.579C>T p.F193= | Silent (SNP) | VAF 192/391 reads (49%) | catalogued as rs1334326472, COSV53162872; called by muse, mutect2, varscan2
- GALNT2 | c.1362T>C p.T454= | Silent (SNP) | VAF 30/321 reads (9%) | called by muse, mutect2, varscan2
- GIPC3 | c.3204A>G p.Q1068= | Silent (SNP) | VAF 119/277 reads (43%) | catalogued as rs768575534; called by muse, mutect2, varscan2
- GOLGA2 | c.2568C>T p.I856= | Silent (SNP) | VAF 184/186 reads (99%) | called by muse, mutect2, varscan2
- GRAMD1A | c.414C>T p.F138= | Silent (SNP) | VAF 219/477 reads (46%) | called by muse, mutect2, varscan2
- GRIN2D | c.1353C>T p.I451= | Silent (SNP) | VAF 263/534 reads (49%) | catalogued as rs1283771530; called by muse, mutect2, varscan2
- GRIP1 | c.3279A>C p.I1093= (on ENST00000359742 / NM_001379345.1; = p.I1041= on NM_021150.4 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 235/446 reads (53%) | called by muse, mutect2, varscan2
- HSP90AB1 | c.438C>T p.I146= | Silent (SNP) | VAF 130/312 reads (42%) | catalogued as COSV62336706; called by muse, mutect2, varscan2
- INSM1 | c.543C>T p.R181= | Silent (SNP) | VAF 241/494 reads (49%) | catalogued as rs1210640403; called by mutect2, varscan2
- ITGAL | c.3000T>C p.Y1000= | Silent (SNP) | VAF 140/296 reads (47%) | called by muse, mutect2, varscan2
- KCTD8 | c.621C>A p.G207= | Silent (SNP) | VAF 273/582 reads (47%) | called by muse, mutect2, varscan2
- KLK15 | c.534A>G p.T178= | Silent (SNP) | VAF 204/396 reads (52%) | called by muse, mutect2, varscan2
- LGI4 | c.1017G>C p.A339= | Silent (SNP) | VAF 289/596 reads (48%) | called by muse, mutect2, varscan2
- MBLAC1 | c.462C>T p.P154= | Silent (SNP) | VAF 342/672 reads (51%) | called by muse, mutect2, varscan2
- MEOX1 | c.414G>C p.G138= | Silent (SNP) | VAF 149/386 reads (39%) | called by muse, mutect2, varscan2
- MOSMO | c.503G>A p.*168= | Silent (SNP) | VAF 81/163 reads (50%) | called by muse, mutect2, varscan2
- MTMR1 | c.1428C>T p.S476= | Silent (SNP) | VAF 142/293 reads (48%) | called by muse, mutect2, varscan2
- NF1 | c.6447G>A p.L2149= (on ENST00000358273 / NM_001042492.3; = p.L2128= on NM_000267.3) | Silent (SNP) | VAF 100/221 reads (45%) | catalogued as COSV62195524; called by muse, mutect2, varscan2
- NLRP3 | c.1698C>T p.F566= | Silent (SNP) | VAF 115/275 reads (42%) | catalogued as rs750708367, CM141590, COSV60226447; called by muse, mutect2, varscan2
- OR4K1 | c.636G>A p.L212= | Silent (SNP) | VAF 128/607 reads (21%) | catalogued as COSV53460460; called by muse, mutect2, varscan2
- ORMDL1 | c.351G>A p.T117= | Silent (SNP) | VAF 108/182 reads (59%) | catalogued as rs761363233; called by muse, varscan2
- PAQR6 | c.156C>T p.I52= | Silent (SNP) | VAF 141/318 reads (44%) | catalogued as COSV52746328; called by muse, mutect2, varscan2
- PDE4B | c.375T>A p.P125= | Silent (SNP) | VAF 150/325 reads (46%) | called by muse, mutect2, varscan2
- PDE4DIP | c.2979G>A p.P993= | Silent (SNP) | VAF 105/286 reads (37%) | catalogued as rs368904679; called by muse, mutect2, varscan2
- PLA2R1 | c.3027C>T p.F1009= | Silent (SNP) | VAF 122/189 reads (65%) | catalogued as COSV51774834; called by muse, mutect2, varscan2
- PLXND1 | c.2841C>T p.I947= | Silent (SNP) | VAF 120/286 reads (42%) | catalogued as COSV60712910; called by muse, mutect2
- POGZ | c.1803C>G p.L601= | Silent (SNP) | VAF 163/387 reads (42%) | called by muse, mutect2, varscan2
- POLR3B | c.570C>T p.I190= | Silent (SNP) | VAF 161/336 reads (48%) | catalogued as rs772944396, COSV57277614; called by muse, mutect2, varscan2
- POU4F1 | c.1053C>T p.N351= | Silent (SNP) | VAF 518/528 reads (98%) | called by muse, varscan2
- PPP1R2C | c.144C>T p.D48= | Silent (SNP) | VAF 185/430 reads (43%) | catalogued as rs1387145560; called by muse, mutect2, varscan2
- PRKD1 | c.1041C>T p.D347= | Silent (SNP) | VAF 169/377 reads (45%) | catalogued as rs975271640; called by muse, mutect2, varscan2
- RBMXL2 | c.603G>A p.P201= | Silent (SNP) | VAF 286/694 reads (41%) | catalogued as rs1255327617; called by muse, mutect2, varscan2
- RYR2 | c.4056C>T p.G1352= | Silent (SNP) | VAF 92/208 reads (44%) | catalogued as rs1487552177; called by muse, mutect2, varscan2
- SLC3A1 | c.1686G>A p.E562= | Silent (SNP) | VAF 165/329 reads (50%) | called by muse, mutect2, varscan2
- SMIM20 | c.339C>A p.G113= (on ENST00000614775; = p.G12= on NM_001145432.1) | Silent (SNP) | VAF 38/593 reads (6%) | called by muse, mutect2
- SPEG | c.1125G>A p.T375= | Silent (SNP) | VAF 211/582 reads (36%) | called by muse, mutect2, varscan2
- SPIRE2 | c.1233G>A p.A411= | Silent (SNP) | VAF 127/477 reads (27%) | catalogued as rs774234787, COSV65556008; called by muse, mutect2, varscan2
- STX4 | c.517T>C p.L173= | Silent (SNP) | VAF 136/266 reads (51%) | called by muse, mutect2, varscan2
- SUPT6H | c.4503C>T p.F1501= | Silent (SNP) | VAF 143/324 reads (44%) | called by muse, varscan2
- SYT13 | c.153G>C p.A51= | Silent (SNP) | VAF 236/530 reads (45%) | catalogued as COSV50072925; called by muse, mutect2, varscan2
- TMEM132A | c.2019C>G p.A673= (on ENST00000453848 / NM_178031.3; = p.A674= on NM_017870.4) | Silent (SNP) | VAF 130/283 reads (46%) | called by muse, mutect2, varscan2
- UGT1A1 | c.642C>G p.L214= | Silent (SNP) | VAF 146/444 reads (33%) | catalogued as COSV100530867; called by muse, mutect2, varscan2
- ZNF721 | c.1428T>C p.F476= (on ENST00000338977; = p.F488= on NM_133474.4) | Silent (SNP) | VAF 144/316 reads (46%) | catalogued as rs1465890661; called by muse, mutect2, varscan2
- CDC25B | c.*921T>A | 3'UTR (SNP) | VAF 285/607 reads (47%) | called by muse, mutect2, varscan2
- KCNQ1 | c.1514+37510G>A | Intron (SNP) | VAF 242/789 reads (31%) | called by muse, mutect2, varscan2
- MIF4GD | c.82+732G>A | Intron (SNP) | VAF 139/299 reads (46%) | catalogued as rs751255378; called by muse, mutect2, varscan2
- PDE4DIP | c.637-7696C>G | Intron (SNP) | VAF 84/346 reads (24%) | catalogued as rs587696242, COSV57730677; called by muse, mutect2, varscan2
- SBNO2 | c.280-4392C>T | Intron (SNP) | VAF 42/580 reads (7%) | called by muse, mutect2
- TAF1 | c.*308del | 3'UTR (DEL) | VAF 98/266 reads (37%) | called by mutect2, pindel, varscan2
- VMA21 | chrX:151396845 C>G | 5'Flank (SNP) | VAF 98/242 reads (40%) | called by mutect2, varscan2
- ZNF37BP | chr10:42555707 C>T | 5'Flank (SNP) | VAF 144/272 reads (53%) | catalogued as rs1168189495; called by muse, mutect2, varscan2
